Somatic mutation profile of tumor specimen TCGA-S8-A6BW-01A (aliquot TCGA-S8-A6BW-01A-11D-A31U-09) from TCGA case TCGA-S8-A6BW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 51.9 years (18,944 days).
Specimen TCGA-S8-A6BW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 780d58c9-b5b1-4e84-9811-f791a8971b28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S8-A6BW-10A (Blood Derived Normal), aliquot TCGA-S8-A6BW-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cb86922-d25c-43ac-9ca4-bcff4503e573

The open-access MAF lists 101 somatic variants for this specimen: 72 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 27, Nonsense Mutation 9, Frame Shift Ins 2, 5'Flank 1, Frame Shift Del 1, RNA 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.377A>C p.Y126S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM115636, COSV52689293, COSV52760406, COSV52970718; called by muse, mutect2
- ATG2B | c.6220C>T p.R2074C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778399547, COSV55890546; called by muse, mutect2
- ATP8B4 | c.3319C>G p.Q1107E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52719295; called by muse, mutect2
- CATSPERD | c.126G>C p.G42= | Splice Region (SNP) | VAF 7/57 reads (12%) | catalogued as COSV62263386; called by muse, mutect2, varscan2
- CDH6 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54074496; called by muse, mutect2, varscan2
- CORO7 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200682379, COSV99227020; called by muse, mutect2
- CRISP1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV100236661, COSV59993214; called by muse, mutect2
- DDX58 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 185/241 reads (77%) | catalogued as rs760856237; called by muse, mutect2, varscan2
- DISP2 | c.4063G>A p.A1355T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs146679685; called by muse, varscan2
- DNAH3 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV54515871; called by muse, mutect2, varscan2
- EFCAB6 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.017); catalogued as COSV53073008; called by muse, mutect2, varscan2
- FSIP2 | c.17691G>A p.M5897I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1308587194; called by muse, mutect2, varscan2
- GCC2 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100565573; called by muse, mutect2, varscan2
- HTT | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1180767981, COSV100751099; called by muse, mutect2, varscan2
- IGSF8 | c.1720A>G p.M574V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs766393697; called by muse, mutect2, varscan2
- MED25 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1388721944; called by muse, mutect2
- MMS19 | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59137023; called by muse, mutect2, varscan2
- MON2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54804309; called by muse, mutect2, varscan2
- MPG | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV54738977; called by muse, mutect2, varscan2
- MVP | c.2632C>T p.Q878* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as rs1261179969; called by muse, mutect2
- NUP107 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.58); catalogued as rs963511613; called by muse, varscan2
- PCDH9 | c.3683C>A p.A1228D (on ENST00000377865 / NM_203487.3; = p.A1194D on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs746411543; called by muse, mutect2, varscan2
- PGR | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 9/13 reads (69%) | catalogued as rs1315135533, COSV54796997; called by muse, mutect2, varscan2
- PTPRD | c.3280G>A p.G1094R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV61990281; called by muse, mutect2, varscan2
- RALGAPA2 | c.2560G>T p.G854C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1340036395, COSV52508589; called by muse, mutect2, varscan2
- RBMY1A1 | c.391+1G>A p.X131_splice | Splice Site (SNP) | VAF 20/194 reads (10%) | catalogued as COSV100385539; called by muse, mutect2, varscan2
- RUFY3 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs772895482, COSV56912788; called by muse, mutect2, varscan2
- SNAI1 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317927184; called by mutect2, varscan2
- VCAN | c.8408A>G p.N2803S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1433895246; called by muse, mutect2, varscan2
- ZFYVE16 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as rs1561274285; called by muse, varscan2
- ZFYVE16 | c.1284C>G p.F428L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV62015838; called by muse, varscan2
- AACS | c.881C>G p.T294R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ACAA2 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO6 | c.418A>G p.M140V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ASXL3 | c.1828G>T p.E610* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- BDP1 | c.4488G>T p.M1496I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, varscan2
- C10orf82 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CHRNB3 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- COL9A1 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2
- ERP44 | c.1183del p.Y395Ifs*6 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- ESRRG | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- GRIA4 | c.2112C>G p.F704L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- H3C8 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- HK2 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HSP90AA1 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- INHBA | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- JAM3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LEPR | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- LRP2 | c.4240T>A p.S1414T | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MFAP1 | c.836_839dup p.V281Efs*19 | Frame Shift Ins (INS) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- MMP26 | c.43T>G p.C15G | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MRPL50 | c.25A>T p.I9F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYB | c.795A>C p.L265F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MYO5C | c.3677A>C p.Q1226P | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR4C16 | c.261G>C p.K87N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2
- PLAG1 | c.1189G>C p.D397H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- PPFIA2 | c.1495C>G p.Q499E | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PRC1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PSD3 | c.2249C>T p.S750L (on ENST00000440756; = p.S749L on NM_015310.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SEMA4B | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB13 | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPICE1 | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.232C>A p.H78N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2
- SRGAP1 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TANC1 | c.5228_5229dup p.W1744Afs*11 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- TTN | c.53221G>A p.E17741K (on ENST00000591111; = p.E10317K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TXNRD1 | c.388A>T p.I130L (on ENST00000525566 / NM_001093771.3; = p.I32L on NM_003330.4) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UBE2G2 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WBP4 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.468); called by muse, mutect2
- XPOT | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- ZNF462 | c.726C>A p.N242K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ZNF804A | c.2926G>T p.A976S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- AKAP3 | c.787C>A p.R263= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV57414766; called by muse, mutect2, varscan2
- AKAP4 | c.957G>A p.Q319= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- ATP2B1 | c.3000C>T p.F1000= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs770458245, COSV99665913; called by muse, mutect2, varscan2
- CACNA1C | c.1980C>G p.L660= | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.4539C>T p.I1513= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- CHD7 | c.8391C>G p.P2797= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- CHST13 | c.933C>T p.I311= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- DNAJB8 | c.555C>T p.S185= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100048099; called by muse, mutect2, varscan2
- GNRH1 | c.37C>T p.L13= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- GREB1 | c.2610C>T p.L870= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV52192789; called by muse, mutect2, varscan2
- HBB | c.63G>T p.V21= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV58943405; called by muse, mutect2, varscan2
- HMGN1 | c.102G>A p.A34= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs1212952107, COSV55742325, COSV99903284; called by muse, mutect2, varscan2
- LRRC37A3 | c.222G>A p.A74= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as rs761269054, COSV59764366; called by muse, mutect2
- MDN1 | c.11121G>A p.V3707= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- MED14 | c.4161C>T p.I1387= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- MRPL4 | c.873C>T p.S291= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs147343809; called by muse, mutect2, varscan2
- OR4K2 | c.844C>T p.L282= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100064472, COSV53851037; called by muse, mutect2
- OVGP1 | c.1665G>A p.E555= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- PRR12 | c.1431C>G p.L477= (on ENST00000615927; = p.L1298= on NM_020719.3) | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- QKI | c.108G>T p.G36= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- RSU1 | c.315C>T p.F105= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs774706517, COSV100590371; called by muse, mutect2, varscan2
- SCAP | c.1257C>T p.L419= | Silent (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- SI | c.324C>T p.F108= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV52300443; called by muse, mutect2, varscan2
- TSHR | c.1596G>A p.K532= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.97242G>C p.V32414= (on ENST00000591111; = p.V24990= on NM_003319.4) | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- TYMS | c.795G>A p.L265= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs549187782; called by muse, mutect2
- VARS2 | c.1323G>A p.K441= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV58912810; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559308 C>T | 5'Flank (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- SNORD115-1 | n.9G>A | RNA (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
